Surgical pathology report (de-identified scan), TCGA case TCGA-UZ-A9PN, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site University of California San Francisco, specimen TCGA-UZ-A9PN-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient Name: [REDACTED]
Med. Rec. #: [REDACTED] Visit #: [REDACTED]
DOB: [REDACTED] Sex: Male
Soc. Sec. #: [REDACTED] Location: [REDACTED]
Physician(s): [REDACTED]

Accession #: [REDACTED]
Service Date: [REDACTED]
Received: [REDACTED]
Client: [REDACTED]

FINAL PATHOLOGIC DIAGNOSIS

Left kidney, nephrectomy: Papillary renal cell carcinoma, 3.0 cm, Fuhrman grade 2, with invasion into perinephric fat; see comment.

COMMENT:

Kidney Tumor Synoptic Comment

- Histologic type: Renal cell carcinoma, papillary type.
- Grade: Fuhrman grade 2.
- Maximum tumor diameter: 3.0 cm.
- Site within kidney: Mid kidney.
- Renal pelvis: Normal.
- Ureter: Normal.
- Renal sinus: Normal, no tumor.
- Hilar renal veins: Normal, no tumor.
- Intrarenal veins and lymphatics: Normal, no tumor.
- Adrenal gland: Not present.
- Capsule/perirenal fat: Tumor penetrates capsule with microscopic growth in perirenal fat.
- Hilar lymph nodes (number positive/number of nodes): None identified; The perihilar fat was dissected, and no definite lymph nodes were identified.
- Resection margins: Negative.
- Proximity to nearest margin: 0.5 cm to Gerota's fascia.
- Stage: pT3aNxMx, Stage III.
- Level sections of A2 and A7 confirms the diagnosis.

ICD-O-3
Carcinoma, papillary renal cell
8260/3
Site: O Kidney NOS
064.9
7/3/20/14

Specimen(s) Received

A: Left kidney and gerotas fascia

Clinical History

The patient is a [REDACTED]-year-old man with a left kidney mass. He undergoes left laparoscopic radical nephrectomy.

[page 2 of 2]
Gross Description

The specimen is received fresh in one part, labeled with the patient's name, medical record number, and "left kidney and Gerota's fascia." It consists of a total nephrectomy specimen, measuring 15.0 x 9.5 x 5.0 cm and weighing 356 gm. The outer surface is inked in black, and the specimen is bisected to reveal a firm brown-tan kidney with a polypoid, yellow-tan mass, measuring 3.0 cm, present in the cortex of the mid kidney. This mass grossly distends the renal capsule and invades the perinephric fat. The fascia is not grossly involved. The mass does not appear grossly to invade into the renal pelvis or intrarenal vessels. The adrenal is not grossly identified. The perihilar fat is dissected and closely examined for lymph nodes. Sections are submitted as follows:

Cassettes A1-A2: Tumor at renal capsule.
Cassettes A3-A4: Tumor in relation to renal pelvis.
Cassette A5: Hilum, including ureter and vessels.
Cassette A6: Representative section of normal kidney.
Cassette A7: Tumor invading perirenal fat.
Cassette A8: Candidate lymph nodes.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

Pathology Resident

Pathologist
Electronically signed out on

Source: NCI Genomic Data Commons file c4038280-4234-4fb0-8e74-1267df893414 (TCGA-UZ-A9PN.FE709840-6A06-4374-A183-0BA1179013A2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).